TCGA case TCGA-FA-A7DS — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Breast; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ed746cb9-0f2f-48ce-923a-3a9f9f00b331

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,087 days); Year of diagnosis: 2013; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 719 days (2.0 years); Ann Arbor extranodal involvement: No; Max tumor bulk site: Breast; Sites of involvement: Lymph node, NOS / Breast, NOS.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Consistent pathology review: Yes; Greatest tumor dimension: 4 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP-14; Days to treatment start: 35 days; Days to treatment end: 127 days; Number of cycles: 6.
   Recorded as not given: Stem Cell Transplantation, NOS.

Follow-up (4 entries)
- Days to follow up: 11 days; Disease response: Tumor Free.
- Days to follow up: 410 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 719 days (2.0 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- CD20 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 60 kg; Height: 157 cm; BMI: 24.3.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FA-A7DS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 780 mg.
  Slide TCGA-FA-A7DS-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
  Slide TCGA-FA-A7DS-01A-02-TSB: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
- Sample TCGA-FA-A7DS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-FA-A7DS-10A, TCGA-FA-A7DS-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: HIV status: Negative.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 1; Bone marrow biopsy performed: No.
- Tests performed, Genetic testing results, Genetic testing result: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 1, New tumor event: Pet scan after treatment results: Not Done; Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 1: Stem cell transplantation: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Adriamycin; Stem cell transplantation: No.
- Drug treatment 4: Pharmaceutical therapy drug name: Prednisolone; Stem cell transplantation: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 719 days; disease-specific survival: no event (censored), 719 days; disease-free interval: no event (censored), 719 days; progression-free interval: no event (censored), 719 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FA-A7DS-01A-11D-A381-01): tumor purity 0.75, ploidy 2.05, whole-genome doublings 0.
